Surgical pathology report (de-identified scan), TCGA case TCGA-G3-AAV6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-AAV6-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
Copied To		Location	
Report Patient	Name		
Demographics (for verification purposes)	Date of Birth:		
	Sex: F		

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A: Gallbladder at
B: Group 8 lymph node at
C: Group 12 lymph node at
D: Left and right liver at
E: Re-excision posterior margin caudate lobe at
Clinical Information
Hepatocellular Ca

ICD-O-3
Carcinoma, hepatocellular 8170/3
Site: Liver C22.0
JAO 6/20/14

Diagnosis

- A. Gallbladder, Resection:
- Cholesterosis
- B. Lymph Node (Group 8), Resection:
- One lymph node, negative for metastatic malignancy (0/1)
- C. Lymph node (Group 2), Resection:
- One lymph node, negative for malignancy 0/1
- D. Liver (left and right lobes), partial hepatectomy:
- Hepatocellular carcinoma, grade 3/4 (size 15cm)
- Multiple foci. Second focus 1.0 cm (D12)
- Lymphovascular invasion present in small vessels near the portal triads. No large vessel invasion identified.
- Vascular margins negative for tumor
- Background liver with chronic nonspecific portal inflammation
- No evidence of cirrhosis
- Present at inked and cauterized hepatic edge
- E. Caudate lobe, posterior margin, reexcision:
- Hepatocellular carcinoma present at edge of specimen towards previous excision. New cauterized margin free of tumor.
Tumor also present in small lymphovascular spaces. No large vessel involvement.

Reported by:
Electronically signed by:
Verified:

Responsible Resident:
Synoptic Report
Specimen:
Liver
Gallbladder

[page 2 of 3]
PROCEDURE:

Partial hepatectomy

TUMOR SIZE:

Greatest dimension: 15 cm

TUMOR FOCALITY:

Multiple (specify location): Multiple present

HISTOLOGIC TYPE:

Minor component of clear cell and multinucleated cell growth patterns noted in the hepatocellular carcinoma

HISTOLOGIC GRADE:

GIII: Poorly differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM):

pMx: Cannot be assessed

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

Gross Description

Received are specimen containers A to E. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and identifiers are labelled with the Surgical Number

A: Received an intact gallbladder 7.4 x 2 x 0.8 cm. The serosal surface is smooth. On opening, it contains approximately 1 ml of thick green bile. No gallstones are identified. The mucosal surface shows cholesterosis. The average thickness of the wall is 0.2 cm. Cystic duct lymph node is not identified. Representative sections are submitted in one block.

B: Specimen is received fresh. The container is designated group 8 lymph node. The specimen consists of a portion of yellow grey soft tissue, possibly lymph node, 2.7 x 1.1 x 0.2 cm. It is trisected and submitted in toto in one cassette.

C: Specimen is received fresh. The container is designated group 12 lymph node. The specimen consists of one portion of yellow tan fibrofatty tissue, 3.4 x 1.2 x 0.3 cm. This fibrofatty tissue contains a single possible lymph node, 2.7 cm in maximum dimension. The lymph node is bisected and submitted in toto in one cassette.

D: Specimen is received fresh. The container is designated left and right liver. The specimen consists of a portion of liver 721 g and 17.5 x 17.5 x 6.5 cm. The resection margin (non peritonealized surface) is painted blue. A necrotic region is identified at the hilum which is painted orange and a possible portal vein margin is painted yellow. On sectioning, a tan irregular mass is identified, 11.3 cm from superior to inferior x 6 cm from anterior to posterior and 15 cm from medial to lateral, almost replacing the liver parenchyma. On sectioning, this mass has a variegated appearance with multiple areas of hemorrhage, necrosis and bright yellow color areas. This mass closely apposes the capsular surface of the liver and in some areas, seems to be grossly invading into the capsule. A solid, tan nodule, 1 cm in maximum dimension is seen separately at a distance of 1 cm from the primary tumor. The residual liver parenchyma appears normal without any gross changes suggestive of cirrhosis.

Sections are submitted as follows:

- D1. resection margin of the possible portal vein
- D2/3. representative sections of the mass to show its closest relationship with the liver capsule
- D4. representative section of the tumor mass to show its relationship with the closest resection margin
- D5-11. representative sections of the tumor mass
- D12. representative section of the tan nodule away from the tumor mass
- D13. section of the tumor mass to show its relationship with the normal liver parenchyma

E: Specimen is received fresh. The container is designated re-excision posterior margin caudate lobe. The specimen consists of one portion of red brown liver tissue, 6.5 x 5 x 0.9 cm. A stapled resection margin is identified, 2 cm in maximum length. The surface is painted blue. On sectioning, tumor masses are not identified grossly. Four representative sections are submitted in E1-4.

Microscopic Description

Minor clear cell and multinucleated cell growth patterns are noted in the hepatocellular carcinoma.

Pathologist Comment

[page 3 of 3]
Note in specimen E blue ink has run onto the surface towards the previous excision and does not represent a true margin. Fibrin and clot is present on this surface and helps separate it from the new true margin.
Best tumor block = D2
Normal = E1

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 8c55981e-8224-4916-86f0-539e904180d3 (TCGA-G3-AAV6.AEA78B89-B8C2-457C-B524-87C19B685C03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).